Gene-level copy-number profile of tumor specimen TCGA-HC-7748-01A from TCGA case TCGA-HC-7748, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.4 years (22,072 days).
Specimen TCGA-HC-7748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.b0b9c638-e19e-4c95-9a57-ded341742dce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-7748-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f99aaf3d-aefb-4a2e-9770-c72144edee1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 5,884; copy number 2: 52,888; copy number 3: 971; copy number 4: 45; copy number 5: 13; copy number 6: 2; copy number 8: 1; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-7748-01A-11D-2112-01): tumor purity 0.47, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,751,512–88,606,976, 13 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,199,823–10,295,579, 8 genes, copy number 5: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,216,416–77,216,878, 1 gene, copy number 6: AC008638.3.
- chr5:74,258,689–74,341,236, 4 genes, copy number 5 (within-gene range 2–5): LINC01335, RN7SL814P, LINC01333, LINC01332.
- chr5:125,966,777–125,968,085, 1 gene, copy number 9: RPSAP37.
- chr5:155,491,336–155,493,598, 1 gene, copy number 8: AC008725.1.
- chr8:122,414,332–122,428,551, 1 gene, copy number 5: SMILR.
- chr16:52,198,012–52,227,956, 1 gene, copy number 6 (within-gene range 2–6): AC007333.2.

Autosomal genes at a single copy (total copy number 1): 3,498. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
